Somatic mutation profile of tumor specimen ALCH-B1ZN-TTP1-A (aliquot ALCH-B1ZN-TTP1-A-1-0-D-A772-36) from ALCHEMIST case ALCH-B1ZN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.4 years (20,960 days).
Specimen ALCH-B1ZN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0642149a-bce5-48be-a255-8fcb18c3dc17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1ZN-NB1-A (Blood Derived Normal), aliquot ALCH-B1ZN-NB1-A-1-0-D-A772-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfba44e5-bc6c-44cd-aa69-55a43605cf47

The open-access MAF lists 297 somatic variants for this specimen: 207 protein-altering or splice-affecting, 52 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 172, Silent 52, Intron 20, Nonsense Mutation 16, Frame Shift Del 8, Splice Site 6, 3'UTR 6, 5'UTR 6, Splice Region 3, 5'Flank 3, RNA 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1511G>T p.G504V (on ENST00000288602 / NM_001374244.1; = p.G464V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 103/329 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs121913348, CM086781, COSV56066746, COSV56075378; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL7A1 | c.8012G>A p.G2671E | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886039329, CM970387; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.3975-1G>T p.X1325_splice | Splice Site (SNP) | VAF 59/244 reads (24%) | catalogued as rs1060500370, CS153440, COSV100647043, COSV62200559; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.157dup p.D53Gfs*110 | Frame Shift Ins (INS) | VAF 25/84 reads (30%) | catalogued as rs1131690917; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ABCB11 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM166697; called by muse, mutect2, varscan2
- ACTC1 | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.093); catalogued as COSV99291630; called by muse, mutect2, varscan2
- ANO1 | c.1891C>T p.R631W | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1328242690, COSV100304331; called by muse, mutect2
- ARHGAP30 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.235); catalogued as rs777142994; called by muse, mutect2, varscan2
- C10orf88 | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV64403595, COSV64403852; called by muse, mutect2, varscan2
- C1orf87 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.063); catalogued as COSV64598360; called by muse, mutect2, varscan2
- CC2D2A | c.4441G>A p.E1481K | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs1349528471, COSV67503254; called by muse, mutect2, varscan2
- CD163L1 | c.1831G>T p.G611C | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV58017424; called by muse, mutect2, varscan2
- CD276 | c.1585G>T p.D529Y (on ENST00000318443 / NM_001024736.2; = p.D311Y on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as COSV59204543; called by muse, mutect2, varscan2
- CFH | c.2902C>A p.P968T | Missense Mutation (SNP) | VAF 66/407 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV100808532; called by muse, mutect2, varscan2
- COLEC11 | c.517C>A p.R173S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52591898; called by muse, mutect2, varscan2
- CPXM2 | c.109G>T p.G37W | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.277); catalogued as COSV53857937; called by muse, mutect2
- DCLRE1A | c.797A>T p.E266V | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV63749833; called by muse, mutect2, varscan2
- DSC3 | c.2458G>T p.E820* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as rs776216296; called by muse, mutect2, varscan2
- ESF1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs764675791; called by muse, mutect2, varscan2
- EXO1 | c.2225A>G p.Y742C | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs375362003; called by muse, mutect2, varscan2
- FAT4 | c.2050G>A p.D684N | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67892512; called by muse, mutect2
- FBLN2 | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55485450; called by muse, mutect2, varscan2
- FERD3L | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV99034439; called by muse, mutect2, varscan2
- FIP1L1 | c.952G>T p.G318C | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100184390; called by muse, mutect2, varscan2
- FOXI1 | c.897G>T p.L299F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as rs938026224, COSV60389215; called by muse, mutect2, varscan2
- FPR1 | c.758G>T p.C253F | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59053302; called by muse, mutect2, varscan2
- GIMAP8 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1203657998, CM153851; called by muse, mutect2, varscan2
- IL27 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1007499231, COSV60493243; called by muse, mutect2, varscan2
- INPPL1 | c.3670G>A p.D1224N | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs1198710450; called by muse, mutect2
- ISL1 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs1328062960; called by muse, mutect2, varscan2
- ITGA7 | c.2923A>T p.S975C (on ENST00000555728; = p.S931C on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99144154; called by muse, mutect2, varscan2
- KRT82 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs377286730; called by muse, mutect2, varscan2
- LPIN1 | c.1536-1G>T p.X512_splice | Splice Site (SNP) | VAF 114/438 reads (26%) | catalogued as COSV99877932; called by muse, mutect2, varscan2
- LVRN | c.1648G>T p.A550S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs369063629, COSV63498638; called by muse, mutect2, varscan2
- MAST4 | c.1356G>T p.E452D (on ENST00000403625 / NM_001164664.2; = p.E263D on NM_015183.3) | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.999); catalogued as COSV55115900; called by muse, mutect2, varscan2
- MGAT4C | c.697T>C p.F233L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59835177; called by muse, mutect2, varscan2
- MS4A5 | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.059); catalogued as rs1227036032, COSV55739925; called by muse, mutect2, varscan2
- MYH8 | c.5793C>A p.H1931Q | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV67970063; called by muse, mutect2, varscan2
- MYL3 | c.245C>A p.A82E | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52767666; called by muse, mutect2, varscan2
- NALCN | c.1236G>T p.R412S | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV51923434; called by muse, mutect2, varscan2
- NECAB1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV101341046; called by muse, mutect2, varscan2
- NF1 | c.3496G>C p.G1166R | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as CS147221, COSV62227948; called by muse, mutect2, varscan2
- NLRP3 | c.2404G>T p.D802Y | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as COSV100276824; called by muse, mutect2, varscan2
- NOS2 | c.2599G>C p.E867Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.85); catalogued as rs1355843628, COSV58221344; called by muse, mutect2, varscan2
- NPAP1 | c.1967del p.P656Rfs*13 | Frame Shift Del (DEL) | VAF 25/85 reads (29%) | catalogued as COSV61504030; called by mutect2, pindel, varscan2
- NPAP1 | c.2264C>A p.A755E | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61507045; called by muse, mutect2, varscan2
- NRP1 | c.2014A>T p.K672* | Nonsense Mutation (SNP) | VAF 28/121 reads (23%) | catalogued as COSV55167024; called by muse, mutect2, varscan2
- OCSTAMP | c.235G>T p.G79* | Nonsense Mutation (SNP) | VAF 66/211 reads (31%) | catalogued as COSV54097664; called by muse, mutect2, varscan2
- OR10AG1 | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV56632040; called by muse, mutect2, varscan2
- OR4C13 | c.164C>A p.S55Y | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs1203449024, COSV73648603, COSV73648757; called by muse, mutect2, varscan2
- PCDHA2 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs782316579; called by muse, varscan2
- PCDHA2 | c.2366C>T p.S789L | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV65366904; called by muse, mutect2
- PGBD2 | c.1089G>T p.L363F | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs887319085; called by muse, mutect2, varscan2
- PHLDB2 | c.2449G>T p.G817W (on ENST00000393925 / NM_001134439.2; = p.G774W on NM_145753.2) | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101208483; called by muse, mutect2, varscan2
- POM121L12 | c.825C>A p.C275* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as rs776790271, COSV68692302; called by muse, mutect2, varscan2
- PORCN | c.1176C>T p.G392= (on ENST00000326194 / NM_203475.3; = p.G381= on NM_022825.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 24/50 reads (48%) | catalogued as rs1556975558, COSV52142104; called by muse, mutect2, varscan2
- PROP1 | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.007); catalogued as rs374712664; called by muse, mutect2
- RFX4 | c.1111G>A p.D371N (on ENST00000392842 / NM_213594.3; = p.D277N on NM_032491.6) | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.037); catalogued as COSV57576431; called by muse, mutect2, varscan2
- RP1L1 | c.4249G>A p.D1417N | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs1261159825, COSV66759144; called by muse, mutect2, varscan2
- SERPINA11 | c.785C>A p.T262N | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.983); catalogued as COSV58241736; called by muse, mutect2, varscan2
- SI | c.376G>T p.V126F | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100013788; called by muse, mutect2, varscan2
- SLC26A3 | c.419C>A p.A140E | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as COSV60640688; called by muse, mutect2, varscan2
- TBX15 | c.1255A>T p.S419C (on ENST00000369429 / NM_001330677.2; = p.S313C on NM_152380.3) | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.524); catalogued as COSV52870690; called by muse, mutect2, varscan2
- TBX3 | c.152C>G p.A51G | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV57471453, COSV57471591; called by muse, mutect2
- TLL2 | c.1050G>T p.A350= | Splice Region (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100780084; called by muse, mutect2, varscan2
- TNNI2 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as COSV53290425; called by muse, mutect2, varscan2
- TNR | c.599C>A p.S200* | Nonsense Mutation (SNP) | VAF 31/136 reads (23%) | catalogued as COSV54883758; called by muse, mutect2, varscan2
- UBR1 | c.3142C>T p.H1048Y | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as rs758995090; called by muse, mutect2, varscan2
- WNK2 | c.1483G>T p.A495S | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52932020; called by muse, mutect2, varscan2
- ZNF257 | c.1139C>A p.A380D | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as COSV71306216; called by muse, mutect2, varscan2
- ACSM5 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ADGRB1 | c.4000A>T p.S1334C | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); called by muse, mutect2
- ADGRB1 | c.4001G>A p.S1334N | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.236); called by muse, mutect2
- AGBL1 | c.1541A>G p.Y514C | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKDD1A | c.139-1G>T p.X47_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- ASXL3 | c.5759A>T p.H1920L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATP8A2 | c.891+2T>A p.X297_splice | Splice Site (SNP) | VAF 29/90 reads (32%) | called by muse, mutect2, varscan2
- BOD1L1 | c.5270G>T p.G1757V | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- C7 | c.2096T>C p.V699A | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1B | c.3254C>A p.T1085K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.103); called by mutect2, varscan2
- CCDC96 | c.134C>G p.S45W | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.366); called by muse, varscan2
- CEP135 | c.414G>C p.K138N | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CEP170 | c.4163G>T p.R1388I | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- CFAP54 | c.7084A>G p.K2362E | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.097); called by muse, varscan2
- CLEC12B | c.739A>G p.K247E | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLEC18C | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- CLEC2B | c.34G>A p.V12I | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL22A1 | c.3042A>C p.E1014D | Missense Mutation (SNP) | VAF 46/253 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPNE4 | c.307A>C p.N103H | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- CRYGD | c.24G>C p.E8D | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CTNNB1 | c.54A>T p.R18S | Missense Mutation (SNP) | VAF 69/225 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- DBX2 | c.722G>T p.W241L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DHX32 | c.997C>G p.Q333E | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DMD | c.3587C>G p.A1196G | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DNM1L | c.84C>G p.I28M | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EIF2AK2 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCRL4 | c.1097G>A p.G366D | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); called by muse, varscan2
- FES | c.197A>T p.D66V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2
- FOXC2 | c.698C>A p.P233H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, varscan2
- FPR1 | c.757T>C p.C253R | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRAS1 | c.9124A>T p.I3042F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FRY | c.5150del p.G1717Vfs*6 | Frame Shift Del (DEL) | VAF 32/152 reads (21%) | called by mutect2, pindel, varscan2
- FTCD | c.925C>A p.L309M | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FUBP3 | c.1592C>G p.A531G | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- FZD6 | c.1993C>T p.Q665* | Nonsense Mutation (SNP) | VAF 83/306 reads (27%) | called by muse, mutect2, varscan2
- GABBR2 | c.1933C>A p.L645M | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- GFPT2 | c.1161A>C p.Q387H | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GLMN | c.358del p.Q120Kfs*13 | Frame Shift Del (DEL) | VAF 63/199 reads (32%) | called by mutect2, pindel, varscan2
- GRIP2 | c.649G>T p.G217C (on ENST00000619221; = p.G120C on NM_001080423.4) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- H2AC17 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- H2AC17 | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC2 | c.8345G>C p.W2782S | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HRH2 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1D-17 | c.24G>T p.Q8H | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- IGKV6D-21 | c.239G>T p.R80M | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- IGSF5 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IPO13 | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITPRID2 | c.3482_3483del p.S1161* | Frame Shift Del (DEL) | VAF 13/103 reads (13%) | called by mutect2, varscan2
- KCNA10 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 29/103 reads (28%) | called by muse, mutect2, varscan2
- KCNH4 | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.139); called by muse, varscan2
- KDM4D | c.577A>T p.T193S | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KEAP1 | c.1349G>T p.W450L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1671 | c.1717G>T p.E573* | Nonsense Mutation (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- LILRB2 | c.1472A>G p.H491R | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, varscan2
- LONP1 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by mutect2, varscan2
- LRP1B | c.4143G>T p.R1381S | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LTBR | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAG | c.1780G>T p.D594Y | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- MAGEB2 | c.896C>A p.T299N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAP2K3 | c.458A>T p.K153M (on ENST00000342679 / NM_145109.3; = p.K124M on NM_002756.4) | Missense Mutation (SNP) | VAF 22/271 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.726); called by muse, mutect2
- MAP3K11 | c.2279C>T p.P760L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- MAP3K4 | c.2225del p.G742Efs*18 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- MC2R | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCUB | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MDGA1 | c.1979T>A p.L660Q | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MSGN1 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- MSLNL | c.1901C>T p.S634L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- MYO1F | c.1143C>A p.S381R | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- N4BP3 | c.91G>C p.A31P | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- NBEA | c.8434G>C p.D2812H | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- NFKB1 | c.2086G>C p.D696H (on ENST00000394820 / NM_001382627.1; = p.D697H on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- NKAPL | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP13 | c.2765C>A p.P922Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- NRXN2 | c.1656C>A p.D552E | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NT5DC2 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by mutect2, varscan2
- OR1E2 | c.362A>G p.D121G | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- OR2T8 | c.704C>A p.A235D | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- PCDH18 | c.858C>A p.S286R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGB6 | c.979C>G p.L327V | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- PEG3 | c.623A>G p.D208G | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP4R4 | c.1043T>A p.L348* | Nonsense Mutation (SNP) | VAF 44/176 reads (25%) | called by muse, mutect2, varscan2
- PRAME | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- PRAMEF2 | c.727del p.H243Ifs*13 | Frame Shift Del (DEL) | VAF 37/169 reads (22%) | called by mutect2, pindel, varscan2
- PSMA1 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 56/364 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, varscan2
- PTPRC | c.2278-2A>G p.X760_splice | Splice Site (SNP) | VAF 60/254 reads (24%) | called by muse, mutect2, varscan2
- PTPRH | c.1078T>G p.C360G | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RAG1 | c.2047del p.E683Rfs*3 | Frame Shift Del (DEL) | VAF 25/104 reads (24%) | called by mutect2, pindel, varscan2
- RASGRF1 | c.320T>C p.L107S | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBL1 | c.350A>C p.E117A | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- RBM10 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 12/19 reads (63%) | called by muse, mutect2, varscan2
- RESF1 | c.1893C>A p.N631K | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RHOJ | c.278C>A p.T93K | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RLF | c.4483C>T p.Q1495* | Nonsense Mutation (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- RNF17 | c.71C>A p.P24H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RPLP2 | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RYR2 | c.11833G>T p.V3945F | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- SAGE1 | c.2148T>A p.Y716* | Nonsense Mutation (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- SELENOV | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC35E3 | c.610C>G p.P204A | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SLC5A7 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPATA16 | c.936C>A p.A312= | Splice Region (SNP) | VAF 68/251 reads (27%) | called by muse, mutect2, varscan2
- SPATA31A3 | c.235C>A p.H79N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.037); called by mutect2, varscan2
- SPHKAP | c.3698G>A p.C1233Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SPRTN | c.1176G>A p.M392I | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- SPRTN | c.1380G>C p.Q460H | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- STRA6 | c.581G>A p.C194Y | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SZT2 | c.4522G>C p.E1508Q (on ENST00000634258 / NM_001365999.1; = p.E1451Q on NM_015284.4) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TBC1D4 | c.3538C>T p.H1180Y | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TCEAL6 | c.525dup p.G176Rfs*26 | Frame Shift Ins (INS) | VAF 18/33 reads (55%) | called by mutect2, pindel, varscan2
- TECTA | c.970G>T p.V324L | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TEP1 | c.7129G>T p.D2377Y | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- TIAM1 | c.4383del p.V1462Sfs*23 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- TIAM1 | c.897A>T p.E299D | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- TIAM1 | c.662G>C p.R221P | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAV8-6 | c.286A>T p.R96W | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- TRBV4-1 | c.251C>G p.S84* | Nonsense Mutation (SNP) | VAF 21/131 reads (16%) | called by muse, mutect2, varscan2
- TRIM49B | c.1208C>A p.P403Q | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- TRIO | c.5144C>T p.S1715L | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2
- TTLL10 | c.1701C>A p.N567K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TYW1 | c.1097A>T p.K366I | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UCHL3 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2, varscan2
- USP20 | c.149A>G p.Y50C | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- USP29 | c.2746G>T p.D916Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.601); called by muse, varscan2
- VEGFC | c.849C>A p.N283K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- VWF | c.6758C>A p.A2253D | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- WDFY4 | c.3163G>A p.G1055R | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDFY4 | c.3646G>T p.G1216* | Nonsense Mutation (SNP) | VAF 59/206 reads (29%) | called by muse, mutect2, varscan2
- YTHDF3 | c.136-1G>T p.X46_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- ZCCHC12 | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.875); called by muse, mutect2
- ZMYND15 | c.2048G>T p.C683F (on ENST00000433935 / NM_001136046.3; = p.C644F on NM_032265.2) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZNF106 | c.2219G>T p.S740I | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ZNF155 | c.1259G>T p.R420I | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- ZNF33A | c.81G>T p.Q27H | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF578 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2, varscan2
- ZNF616 | c.1792G>T p.V598F | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- ZNF773 | c.619G>T p.V207F | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNRF3 | c.2158C>T p.P720S (on ENST00000544604 / NM_001206998.2; = p.P620S on NM_032173.3) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- A1BG | c.1077C>T p.F359= | Silent (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- ABCC10 | c.1890C>T p.G630= (on ENST00000372530 / NM_001198934.2; = p.G602= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as rs1290212946; called by muse, mutect2, varscan2
- ABCC9 | c.3798G>T p.V1266= | Silent (SNP) | VAF 72/281 reads (26%) | called by muse, mutect2, varscan2
- ACTG2 | c.331C>T p.L111= | Silent (SNP) | VAF 22/105 reads (21%) | called by muse, mutect2
- ADAMTS18 | c.633C>T p.I211= | Silent (SNP) | VAF 55/224 reads (25%) | catalogued as rs765104436; called by muse, mutect2, varscan2
- AGT | c.801G>T p.L267= | Silent (SNP) | VAF 45/202 reads (22%) | catalogued as COSV64184484, COSV64185136; called by muse, mutect2, varscan2
- AHCYL2 | c.219C>T p.L73= | Silent (SNP) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- ARL15 | c.246A>G p.E82= | Silent (SNP) | VAF 30/115 reads (26%) | called by muse, varscan2
- AUTS2 | c.3069C>G p.P1023= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV61392208, COSV61406310; called by muse, mutect2, varscan2
- CCDC178 | c.1536C>A p.T512= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV100286603; called by muse, mutect2, varscan2
- CFAP92 | c.909A>T p.S303= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- COL6A6 | c.4269C>T p.I1423= | Silent (SNP) | VAF 48/289 reads (17%) | catalogued as rs375056319; called by muse, mutect2, varscan2
- COPA | c.3288G>T p.L1096= | Silent (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- DENND5A | c.813C>T p.C271= | Silent (SNP) | VAF 43/178 reads (24%) | catalogued as COSV60233826; called by muse, mutect2, varscan2
- DGKZ | c.1992C>T p.N664= (on ENST00000454345 / NM_001105540.2; = p.N476= on NM_003646.4) | Silent (SNP) | VAF 24/104 reads (23%) | called by muse, mutect2, varscan2
- EBF3 | c.87G>T p.S29= | Silent (SNP) | VAF 27/97 reads (28%) | called by muse, mutect2, varscan2
- ERCC4 | c.1407T>G p.P469= | Silent (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- FANCI | c.1377C>T p.F459= | Silent (SNP) | VAF 37/276 reads (13%) | called by muse, mutect2, varscan2
- FBXO46 | c.247C>A p.R83= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as COSV58348018; called by muse, mutect2
- FHOD3 | c.450G>T p.L150= | Silent (SNP) | VAF 79/285 reads (28%) | catalogued as COSV57184297; called by muse, mutect2, varscan2
- FRY | c.8895G>C p.L2965= | Silent (SNP) | VAF 28/234 reads (12%) | called by muse, mutect2, varscan2
- GBP3 | c.1644C>T p.L548= | Silent (SNP) | VAF 27/217 reads (12%) | catalogued as rs766742474; called by muse, mutect2, varscan2
- GSTA4 | c.558G>A p.V186= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs969684214; called by muse, mutect2, varscan2
- H1-2 | c.540G>A p.A180= | Silent (SNP) | VAF 26/199 reads (13%) | catalogued as rs773564861, COSV59189483, COSV59190009, COSV59190715; called by muse, mutect2, varscan2
- ITGAV | c.2505T>C p.N835= | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as rs774735553, COSV99655695; called by mutect2, varscan2
- KATNIP | c.546G>T p.L182= | Silent (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- LMBR1 | c.261C>A p.I87= | Silent (SNP) | VAF 28/204 reads (14%) | catalogued as rs772709122; called by muse, mutect2, varscan2
- LRBA | c.7032C>T p.S2344= | Silent (SNP) | VAF 39/300 reads (13%) | catalogued as COSV100841902; called by muse, mutect2, varscan2
- LRRC18 | c.93C>T p.R31= | Silent (SNP) | VAF 36/151 reads (24%) | called by muse, mutect2, varscan2
- LRRC66 | c.1455G>A p.S485= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV58633639; called by muse, mutect2, varscan2
- MRPL1 | c.258C>G p.V86= | Silent (SNP) | VAF 20/214 reads (9%) | catalogued as rs146085944; called by muse, mutect2
- MS4A15 | c.474C>T p.L158= (on ENST00000405633 / NM_001098835.2; = p.L65= on NM_152717.3) | Silent (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- OR4P4 | c.144G>T p.T48= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs745780696, COSV58923895; called by muse, mutect2, varscan2
- OR6Q1 | c.402C>A p.L134= | Silent (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- PCDHB7 | c.1713C>A p.P571= | Silent (SNP) | VAF 29/141 reads (21%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.777G>T p.T259= | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as COSV53951072; called by muse, mutect2, varscan2
- PKD1 | c.12414C>A p.R4138= (on ENST00000262304 / NM_001009944.3; = p.R4137= on NM_000296.4) | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- POTEE | c.2295G>A p.L765= | Silent (SNP) | VAF 5/27 reads (19%) | called by mutect2, varscan2
- PTPRJ | c.1332G>T p.T444= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs1227749859; called by muse, mutect2
- RTKN | c.717A>T p.S239= (on ENST00000272430 / NM_001015055.2; = p.S226= on NM_033046.2) | Silent (SNP) | VAF 30/87 reads (34%) | called by muse, mutect2, varscan2
- RYR2 | c.4974C>A p.L1658= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV63720129; called by muse, varscan2
- SAGE1 | c.1605C>A p.V535= | Silent (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- SCNN1D | c.738G>A p.A246= (on ENST00000338555; = p.A410= on NM_001130413.4) | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs747905771; called by muse, mutect2, varscan2
- SDK1 | c.2058G>T p.V686= | Silent (SNP) | VAF 66/229 reads (29%) | catalogued as COSV101269046; called by muse, mutect2, varscan2
- SLC6A19 | c.93C>T p.S31= | Silent (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2, varscan2
- SNED1 | c.786G>T p.V262= | Silent (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- STARD9 | c.3363A>T p.I1121= | Silent (SNP) | VAF 79/259 reads (31%) | called by muse, mutect2, varscan2
- TP53TG3D | c.318A>C p.T106= | Silent (SNP) | VAF 49/197 reads (25%) | catalogued as rs764850506; called by muse, mutect2, varscan2
- USH2A | c.6933C>A p.A2311= | Silent (SNP) | VAF 64/296 reads (22%) | called by muse, mutect2, varscan2
- USP25 | c.2643C>G p.L881= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV53483921; called by muse, varscan2
- ZNRF3 | c.2157C>A p.S719= (on ENST00000544604 / NM_001206998.2; = p.S619= on NM_032173.3) | Silent (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- ZSCAN29 | c.1332A>C p.A444= | Silent (SNP) | VAF 48/316 reads (15%) | called by muse, mutect2, varscan2
- AC011840.1 | n.880C>T | RNA (SNP) | VAF 52/208 reads (25%) | called by muse, mutect2, varscan2
- ACAD8 | c.-21G>A | 5'UTR (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- ARMC6 | c.30-1962G>T | Intron (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- BLK | c.1030-16G>T | Intron (SNP) | VAF 6/30 reads (20%) | called by mutect2, varscan2
- BPNT1 | c.*1113C>G | 3'UTR (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- CISD2 | c.103+322C>G | Intron (SNP) | VAF 18/192 reads (9%) | called by muse, mutect2
- CRB1 | c.1172-7033C>T | Intron (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2
- CRB1 | c.1172-7031T>G | Intron (SNP) | VAF 8/98 reads (8%) | catalogued as rs1379104172; called by muse, mutect2
- CSMD3 | c.-8C>A | 5'UTR (SNP) | VAF 27/133 reads (20%) | called by muse, mutect2, varscan2
- DECR1 | c.70-1477G>C | Intron (SNP) | VAF 17/119 reads (14%) | called by muse, mutect2, varscan2
- DPP3 | c.*263A>T | 3'UTR (SNP) | VAF 37/115 reads (32%) | called by muse, mutect2, varscan2
- EFNB1 | c.*27A>T | 3'UTR (SNP) | VAF 18/28 reads (64%) | called by muse, mutect2, varscan2
- FCGRT | c.601+1694A>G | Intron (SNP) | VAF 10/136 reads (7%) | catalogued as rs1422629374; called by muse, mutect2
- FSIP2 | c.-18G>A | 5'UTR (SNP) | VAF 8/58 reads (14%) | called by mutect2, varscan2
- GPI | c.122+336G>T | Intron (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- HELLS | c.1326+983G>T | Intron (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- KRT6B | c.-32C>A | 5'UTR (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- LEKR1 | c.*876A>T | 3'UTR (SNP) | VAF 5/13 reads (38%) | catalogued as rs765360868; called by muse, mutect2, varscan2
- MINPP1 | c.-2C>T | 5'UTR (SNP) | VAF 6/53 reads (11%) | catalogued as rs544545168; called by muse, mutect2, varscan2
- MIR6080 | chr17:64780393 C>A | 5'Flank (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- MYO7B | c.6249+108C>T | Intron (SNP) | VAF 33/107 reads (31%) | catalogued as rs1452841869; called by muse, mutect2, varscan2
- NDUFAF5 | c.*10C>T | 3'UTR (SNP) | VAF 20/199 reads (10%) | catalogued as rs772294308; called by muse, varscan2
- OR2P1P | chr6:29076338 A>G | 5'Flank (SNP) | VAF 16/58 reads (28%) | catalogued as rs900980149; called by muse, mutect2, varscan2
- PACS2 | c.2032-27C>T | Intron (SNP) | VAF 4/63 reads (6%) | catalogued as rs1555414726; called by muse, mutect2
- PCDH15 | c.2868+48C>G | Intron (SNP) | VAF 22/115 reads (19%) | catalogued as rs751797206, COSV100213226; called by muse, mutect2, varscan2
- POLR2M | c.113+145C>G | Intron (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- RN7SL495P | chr15:22611249 C>G | 5'Flank (SNP) | VAF 45/286 reads (16%) | called by muse, mutect2, varscan2
- SIGLEC17P | n.544G>C | RNA (SNP) | VAF 31/100 reads (31%) | called by muse, mutect2, varscan2
- SNAP25 | c.164-247C>A | Intron (SNP) | VAF 28/95 reads (29%) | catalogued as COSV54775755; called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25088191 G>T | 3'Flank (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- SPATS2L | c.39+3937C>T | Intron (SNP) | VAF 16/153 reads (10%) | called by muse, mutect2, varscan2
- TMTC4 | c.163-1660G>T | Intron (SNP) | VAF 40/113 reads (35%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.1047+1052G>A | Intron (SNP) | VAF 21/178 reads (12%) | called by muse, mutect2, varscan2
- TRPM3 | c.1278+28T>A | Intron (SNP) | VAF 34/222 reads (15%) | called by muse, mutect2, varscan2
- UBE2D3 | c.-4G>C | 5'UTR (SNP) | VAF 25/234 reads (11%) | called by muse, mutect2, varscan2
- VASH2 | c.497+789G>T | Intron (SNP) | VAF 62/310 reads (20%) | called by muse, mutect2, varscan2
- VSTM1 | c.*37C>A | 3'UTR (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100618674, COSV100618818; called by muse, mutect2
- XKR6 | c.764+76599G>A | Intron (SNP) | VAF 39/180 reads (22%) | called by muse, mutect2, varscan2
